Somatic mutation profile of tumor specimen TCGA-R6-A6L4-01A (aliquot TCGA-R6-A6L4-01A-11D-A31U-09) from TCGA case TCGA-R6-A6L4, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 28.0 years (10,222 days).
Specimen TCGA-R6-A6L4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ebbab3-4c08-4fe0-8f4d-0b43c18fdc50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6L4-10A (Blood Derived Normal), aliquot TCGA-R6-A6L4-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89ee940e-3897-48ac-a9a1-638465cc6ece

The open-access MAF lists 113 somatic variants for this specimen: 91 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 20, Nonsense Mutation 6, Splice Region 3, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.3427C>T p.H1143Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs1555614963, CS031791; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); catalogued as rs771831816, COSV68457398; called by muse, mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD17C | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99358899; called by muse, mutect2, varscan2
- ACP3 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60484807; called by muse, mutect2, varscan2
- ASXL1 | c.3823T>C p.S1275P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV60104625; called by muse, mutect2, varscan2
- ATP8B4 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52726883; called by muse, mutect2, varscan2
- BCHE | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs534912670, COSV52253705; called by muse, mutect2, varscan2
- CCDC57 | c.479T>C p.L160P | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66432758; called by muse, mutect2, varscan2
- CDK14 | c.1315C>A p.P439T (on ENST00000380050 / NM_001287135.2; = p.P421T on NM_012395.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99724025; called by muse, mutect2, varscan2
- CHST9 | c.1009T>G p.L337V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV104370430; called by muse, mutect2, varscan2
- CNGB3 | c.1710A>C p.Q570H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs775564107, COSV60694300; called by muse, mutect2, varscan2
- CPNE5 | c.136C>T p.L46= | Splice Region (SNP) | VAF 18/53 reads (34%) | catalogued as rs755213428, COSV99782663; called by muse, mutect2, varscan2
- ERBB4 | c.353C>A p.A118E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53547173; called by muse, mutect2, varscan2
- FBXW7 | c.1607C>G p.T536R (on ENST00000281708 / NM_001349798.2; = p.T456R on NM_018315.5) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV55900575, COSV55952091; called by muse, mutect2, varscan2
- FHOD3 | c.946A>C p.N316H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV57177638; called by muse, mutect2, varscan2
- FLRT2 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as rs765263836; called by muse, mutect2, varscan2
- FOXD4L5 | c.920T>A p.L307H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1163954615; called by mutect2, varscan2
- GCNT1 | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057664; called by muse, mutect2, varscan2
- HMCN1 | c.7555C>T p.P2519S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.192); catalogued as rs865790846, COSV99624075; called by muse, mutect2, varscan2
- KANK4 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.783); catalogued as COSV62986804; called by muse, mutect2, varscan2
- KCNN3 | c.1523A>C p.N508T (on ENST00000618040 / NM_001204087.1; = p.N493T on NM_002249.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV55220221; called by muse, mutect2, varscan2
- KLK2 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320097; called by muse, mutect2, varscan2
- LRRIQ3 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV63042039; called by muse, mutect2
- NOD2 | c.540G>A p.R180= | Splice Region (SNP) | VAF 10/21 reads (48%) | catalogued as rs1046223267; called by muse, mutect2, varscan2
- NRG3 | c.2059G>A p.E687K (on ENST00000404547 / NM_001370084.1; = p.E663K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs757060096, COSV99058677; called by muse, mutect2, varscan2
- OPRL1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.826); catalogued as rs774239511, COSV100402110; called by muse, mutect2
- PCDHA7 | c.128A>C p.N43T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781858636; called by muse, mutect2, varscan2
- PCDHB12 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs782365765, COSV53394584, COSV53400433; called by muse, mutect2, varscan2
- PCNX1 | c.3761T>G p.L1254R | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1275384613; called by muse, mutect2, varscan2
- PHF7 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.513); catalogued as rs868656396; called by muse, mutect2, varscan2
- PLSCR5 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV101494484; called by muse, mutect2, varscan2
- PPP1R16B | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55386343; called by muse, mutect2, varscan2
- RELN | c.6794T>C p.L2265P | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.591); catalogued as rs1432646080; called by muse, mutect2
- SLC17A5 | c.1465G>C p.D489H | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779656808; called by muse, mutect2, varscan2
- ZFHX3 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs745871900, COSV51714434; called by muse, mutect2, varscan2
- ZNF28 | c.1872C>G p.I624M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as COSV60422897; called by muse, mutect2, varscan2
- ABCA6 | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL121899.2 | c.440T>G p.L147R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANK3 | c.8982G>T p.L2994F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOB | c.1473C>A p.V491= | Splice Region (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- ASTN2 | c.2312A>G p.D771G (on ENST00000313400 / NM_001365069.1; = p.D720G on NM_014010.5) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- BCHE | c.272A>C p.N91T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- CACNA1S | c.2777G>A p.S926N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- CARF | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CCDC88A | c.1855C>T p.H619Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CD109 | c.2785T>G p.F929V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUSP10 | c.391A>C p.S131R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EDNRA | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EFCAB6 | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FCGBP | c.10848_10849del p.C3616* | Nonsense Mutation (DEL) | VAF 8/45 reads (18%) | called by pindel, varscan2
- GK2 | c.35T>C p.L12S | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- HYDIN | c.9934C>A p.P3312T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- IGSF10 | c.6343G>C p.G2115R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT20 | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRT72 | c.1085A>C p.K362T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LIMS1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.686); called by muse, mutect2
- MEIS1 | c.950T>G p.L317R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCAPG | c.2360C>T p.S787F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2
- NOTCH4 | c.4068C>A p.D1356E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G9 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR1J4 | c.196T>G p.L66V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1L4 | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, varscan2
- OR56B1 | c.661A>C p.S221R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2
- PRAMEF18 | c.587G>T p.R196I | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PTGES2 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PYHIN1 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RAB27A | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- RYR2 | c.11653A>G p.I3885V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SELENOV | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SLC16A9 | c.1514T>G p.V505G | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNAP91 | c.2017T>G p.F673V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- STARD13 | c.680T>C p.L227P (on ENST00000336934 / NM_001243476.3; = p.L109P on NM_052851.3) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.2400A>T p.K800N (on ENST00000367255 / NM_182961.4; = p.K807N on NM_033071.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBX22 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- THAP9 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- TOP1 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TOP1 | c.1724A>C p.K575T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRAJ14 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- TRPC1 | c.974C>T p.S325F (on ENST00000476941 / NM_001251845.2; = p.S291F on NM_003304.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRPV2 | c.1852T>G p.F618V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TYK2 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UNC13A | c.3129G>T p.K1043N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- USH2A | c.3725C>A p.P1242H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- USP9Y | c.4432C>T p.Q1478* | Nonsense Mutation (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- WDR17 | c.3841A>T p.K1281* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- WDR46 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZEB1 | c.1837A>C p.K613Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF222 | c.996A>C p.Q332H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF397 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF43 | c.1990A>G p.T664A | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- AP3B2 | c.2778A>G p.Q926= (on ENST00000261722; = p.Q920= on NM_004644.5) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55614290; called by muse, mutect2, varscan2
- AXDND1 | c.3021T>C p.S1007= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- CSDE1 | c.885A>G p.K295= (on ENST00000358528 / NM_001007553.3; = p.K264= on NM_007158.6) | Silent (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- FASLG | c.606C>T p.C202= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- FCGBP | c.2826G>A p.V942= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- FCRL1 | c.994A>C p.R332= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1161741113; called by muse, mutect2, varscan2
- GRIN2A | c.1794T>G p.S598= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV58018335, COSV58049640; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1842C>A p.I614= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV61145212; called by muse, mutect2, varscan2
- IRX1 | c.348T>G p.A116= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1464441355, COSV57358402, COSV57358593, COSV57363094; called by muse, mutect2, varscan2
- KANK4 | c.165T>C p.I55= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1303720064; called by muse, mutect2, varscan2
- MAGEL2 | c.2340G>A p.P780= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- NCAPG | c.2358A>T p.A786= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- NOL8 | c.2301G>A p.A767= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs763859897, COSV100694551, COSV62636207; called by muse, mutect2, varscan2
- NR1D1 | c.1368C>T p.H456= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1205693170; called by muse, mutect2, varscan2
- OR5M11 | c.573T>G p.T191= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV101602073, COSV73141966; called by muse, mutect2, varscan2
- PTPRG | c.1443G>A p.T481= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs544886184; called by muse, mutect2, varscan2
- SPATA31E1 | c.3231A>C p.S1077= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- TMTC1 | c.2127T>G p.A709= (on ENST00000539277 / NM_001193451.2; = p.A601= on NM_175861.3) | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- TPO | c.435T>C p.T145= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV61096136; called by muse, mutect2, varscan2
- TTN | c.19612A>C p.R6538= (on ENST00000591111; = p.R5611= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MAPK10 | c.*119T>A | 3'UTR (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- PITX2 | c.185-965C>T | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
